CCDI case PBCAWW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/04eb2146-b611-4194-b3e1-9c5c4e28878e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 13.5 years (4,943 days).

Biospecimens (3 samples)
- Sample 0DOQG4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOQG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOQGM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
